Surgical pathology report (de-identified scan), TCGA case TCGA-67-4679, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site St Joseph's Medical Center (MD), specimen TCGA-67-4679-01B (Primary Tumor).

[page 1 of 5]
ENTERED:

SP TYPE: SURGICAL P

OTHR DR:

ORDERED: 88307/6, LEVEL V - GROSS/6

SURGICAL PROCEDURES:

REGIONAL LYMPH

CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: RT LUNG CANCER

GROSS DESCRIPTION

- A. The specimen is submitted fresh as "10L lymph left tracheobronchial angle" and consists of five reddish black lymph nodes ranging 0.4 cm to 0.7 cm in dimension; submitted, 5 (1).
- B. The specimen is submitted fresh as "10R right tracheobronchial angle" and consists of two reddish black lymph nodes measuring 0.6 cm and 0.8 cm in dimension; submitted, 2 (1).
- C. The specimen is submitted fresh as "2R right upper paratracheal" and consists of two reddish yellow lymph nodes measuring 0.8 cm and 1.5 cm in dimension; sectioned and submitted, 3 (1).
- D. The specimen is submitted fresh as "4R right lower paratracheal" and consists of four reddish yellow lymph nodes ranging 0.5 cm to 1.5 cm in dimension; submitted in toto, 4 (1).
- E. The specimen is submitted fresh as "3A lower pretracheal" and consists of four reddish black lymph nodes ranging 0.9 cm to 1.4 cm in dimension; submitted, 4 (1).
- F. The specimen is submitted fresh as "7 subcarinal" and consists of multiple reddish black lymph nodes measuring 3 x 3 x 0.8 cm in aggregate; submitted in toto, multiple (2).

[page 2 of 5]
FINAL DIAGNOSIS

- A. "LEVEL 10L LEFT TRACHEOBRONCHIAL ANGLE LYMPH NODES": MULTIPLE ANTHRACOTIC LYMPH NODES NEGATIVE FOR TUMOR.
- B. "LEVEL 10R RIGHT TRACHEOBRONCHIAL ANGLE LYMPH NODES": MULTIPLE ANTHRACOTIC LYMPH NODES NEGATIVE FOR TUMOR.
- C. "LEVEL 2R RIGHT UPPER PARATRACHEAL LYMPH NODES": MULTIPLE ANTHRACOTIC LYMPH NODES NEGATIVE FOR TUMOR.
- D. "LEVEL 4R RIGHT LOWER PARATRACHEAL LYMPH NODES": MULTIPLE ANTHRACOTIC LYMPH NODES NEGATIVE FOR TUMOR.
- E. "LEVEL 3A LOWER PRETRACHEAL LYMPH NODES": MULTIPLE ANTHRACOTIC LYMPH NODES NEGATIVE FOR TUMOR.
- F. "LEVEL 7 SUBCARINAL LYMPH NODES": MULTIPLE ANTHRACOTIC LYMPH NODES NEGATIVE FOR TUMOR.

Signed (Electronically) < SIGNATURE ON

Patient: [REDACTED]

Age/Sex: [REDACTED]

Acct# [REDACTED]

Unit# [REDACTED]

[page 3 of 5]
ENTERED:
ORDERED:

PRIORITY: FROZEN SEC

SURGICAL PROCEDURES:

LYMPH NODE, RESECTION, REGIONAL LYMPH

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "level 9R" and consists of two anthracotic nodes measuring 0.5 and 0.9 cm in dimension; submitted, 2 (1) labeled "FSP" and used for frozen section.

FROZEN SECTION DIAGNOSIS: Two lymph nodes negative for tumor. ■■

B. The specimen is submitted fresh but not for frozen section as "right lower lobar node" and consists of two grey black ovoid glistening possible lymph nodes measuring 0.4 cm and 0.6 cm in greatest dimension. Each is submitted in toto, 2 (1).

C. The specimen is submitted fresh but not for frozen section as "right lower lobe" and consists of a 390 gram (formalin fixed), 16 x 13 x 4 cm lung lobectomy received with a 8 cm in length stapled margin, multiple stapled vasculature margins measuring 0.5 cm in length by 0.3 cm in diameter to 1 cm in length by 0.8 cm in diameter and a stapled bronchial margin measuring 0.5 cm in length by 2.5 cm in diameter. The pleural surface is pink to red, glistening and smooth with focal areas of anthracotic pigmentation and a 1 cm area in greatest dimension somewhat ragged and disrupted surface. The pleural surface overlying this area is inked blue. The stapled resection margin is removed and the underlying parenchyma is inked black. The lung lobe is serially sectioned to reveal a 12.5 x 7 x 3 cm well delineated tan to brown firm area extending through nearly the entire lobe and corresponding to the previously described ragged and disrupted area on the pleural surface and grossly appearing to abut the overlying pleural surface measuring 2.2 cm from the bronchus. Adjacent to this area but grossly appearing not to be contiguous is a 3.5 x 3 x 2.6 cm ill defined, diffusely firm multinodular area measuring 0.4 cm from the closest pleural surface, 1 cm from the closest parenchyma underlying the stapled margin, and 2.8 cm from the bronchus. The remaining uninvolved parenchyma is pink red, spongy, homogenous and

Patient: ■■■■■■■■■■■■

Age/Sex: ■■■

Acct# ■■■■■■■■■■

■■■■■■■■■■

[page 4 of 5]
atient: [REDACTED]

ACCT#: [REDACTED]

(Continued)

GROSS DESCRIPTION

(Continued)

grossly unremarkable. No other discrete masses or nodularities are grossly identified. Also identified at the hilum is a 1 cm in greatest dimension gray black hilar lymph node which is bisected and submitted entirely. Representative sections are submitted, multiple (13):

Cassette 1: Vasculature margins submitted en face.
Cassette 2: Bronchial margin submitted en face.
Cassette 3: Multinodular area with closest blue inked pleural surface.
Cassettes 4 & 5: Additional sections of multinodular area.
Cassette 6: Interface of multinodular area with adjacent well delineated area.
Cassette 7: Perpendicular section of the parenchyma underlying the stapled margin closest to multinodular and firm areas.
Cassettes 8 - 11: Representative sections of diffusely firm area.
Cassette 12: Uninvolved parenchyma and pleural surface.
Cassette 13: One possible lymph node, bisected.

FINAL DIAGNOSIS

- A. MEDIASTINAL LYMPH NODES, LEVEL 9R: TWO LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY.
- B. "RIGHT LOWER LOBE NODES": TWO LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY.
- C. LOWER LOBE, RIGHT LUNG (LOBECTOMY SPECIMEN): WELL DIFFERENTIATED BRONCHIOLOALVEOLAR ADENOCARCINOMA, GRADE I, 12.5 CM MAXIMUM DIAMETER, WITH ADDITIONAL SMALLER MULTINODULAR AREA OF HISTOLOGICALLY IDENTICAL TUMOR ALSO NOTED. THE LESION EXTENDS TO WITHIN 2.8 CM OF THE BRONCHIAL MARGIN AT ITS CLOSEST APPROACH AND EXTENDS TO, BUT DOES NOT INVADE, THE PLEURAL SURFACE. BRONCHIAL AND VASCULAR MARGINS AND A SINGLE HILAR LYMPH NODE ARE FREE OF DISEASE.

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY
LATERALITY: RIGHT
TUMOR SITE: RIGHT LOWER LOBE
TUMOR SIZE: 12.5 CM MAXIMUM DIAMETER
HISTOLOGIC TYPE: BRONCHIOLOALVEOLAR ADENOCARCINOMA

Patient: [REDACTED]

Age/Sex: [REDACTED]

Unit: [REDACTED]

[page 5 of 5]
atient: [REDACTED]

ACCT#: [REDACTED]

(Continued)

SYNOPTIC REPORT

(Continued)

HISTOLOGIC GRADE: 1

EXTENT OF INVASION: CONFINED TO LUNG

EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): NONE IDENTIFIED

ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC: (SEE NARRATIVE)

MARGINS:

BRONCHIAL: UNINVOLVED

PARENCHYMAL: N/A

VASCULAR: UNINVOLVED

DISTANCE TO PERTINENT MARGIN(S) (AS APPLICABLE): 2.8 CM FROM BRONCHIAL MARGIN

VENOUS INVASION: ABSENT

ARTERIAL (LARGE VESSEL) INVASION: ABSENT

LYMPH NODE:

f, , , , N1 - # INVOLVED/# EXAMINED: 0/1

f, , , , N2 - # INVOLVED/# EXAMINED: 0/MULTIPLE

f, , , , N3 - # INVOLVED/# EXAMINED: 0/MULTIPLE

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

pTNM STAGE: pT3 N0 Mx

Signed (Electronically) < SIGNATURE ON FILE > [REDACTED]

atient: [REDACTED]

Age/Sex: [REDACTED]

Acct: [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 0118d60f-56db-4024-a68b-0d9d609fe7a5 (TCGA-67-4679.3528CCEC-AFFF-4212-97AA-1D4F7AF79856.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).